Somatic mutation profile of tumor specimen BA2229D (aliquot aq-BA2229D) from BEATAML1.0 case 2240, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.5 years (22,454 days).
Specimen BA2229D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93c4925f-ef29-41de-8511-50e87294a18a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2767D (Solid Tissue Normal), aliquot aq-BA2767D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/981ac02e-c38f-4164-9e5b-d1689800cbc1

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Splice Site 1, RNA 1, Splice Region 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IKZF1 | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs374333820, COSV58786758; ClinVar: pathogenic; called by mutect2, varscan2
- FASN | c.2557G>A p.G853S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.433); catalogued as rs759542635, COSV60761623; called by muse, mutect2, varscan2
- FGF9 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV66645707; called by muse, mutect2, varscan2
- LANCL3 | c.305C>A p.A102E | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.143); catalogued as rs1556415677; called by muse, mutect2
- MED15 | c.2260C>T p.R754C (on ENST00000263205 / NM_001003891.3; = p.R714C on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs750737988, COSV53028711; called by muse, mutect2, varscan2
- PRKAR2B | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs76105568, COSV99708384; called by muse, mutect2, varscan2
- TMEM132C | c.2797G>C p.V933L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59419281; called by muse, mutect2, varscan2
- TPBGL | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1430516689; called by muse, mutect2
- USP19 | c.1846G>T p.V616L | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV60046630; called by muse, mutect2
- ANAPC1 | c.2617G>T p.V873L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- BCOR | c.3723_3732del p.Q1242Pfs*49 (on ENST00000378444 / NM_001123385.2; = p.Q1208Pfs*49 on NM_017745.6) | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | called by mutect2, pindel, varscan2
- KCNQ2 | c.1023+7C>A | Splice Region (SNP) | VAF 60/193 reads (31%) | called by mutect2, varscan2
- KIF11 | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC29A4 | c.-11-1G>A | Splice Site (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- TSPYL2 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, varscan2
- DEF8 | c.204G>A p.L68= (on ENST00000268676 / NM_207514.3; = p.L7= on NM_017702.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs771260753; called by muse, mutect2, varscan2
- INPP5J | c.2115G>A p.V705= (on ENST00000331075 / NM_001284285.2; = p.V337= on NM_001002837.2) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs765506251; called by muse, varscan2
- TAF6L | c.381C>A p.V127= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- GDI1 | c.46-18G>T | Intron (SNP) | VAF 22/110 reads (20%) | called by muse, varscan2
- SSPOP | n.13045C>A | RNA (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
